Somatic mutation profile of tumor specimen TCGA-D3-A1Q8-06A (aliquot TCGA-D3-A1Q8-06A-11D-A19A-08) from TCGA case TCGA-D3-A1Q8, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 33.8 years (12,330 days).
Specimen TCGA-D3-A1Q8-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd632709-021f-488e-a1b0-13423d80b814.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A1Q8-10A (Blood Derived Normal), aliquot TCGA-D3-A1Q8-10A-01D-A19A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07f79d00-250d-4f4d-9b66-e90b3322bc58

The open-access MAF lists 277 somatic variants for this specimen: 179 protein-altering or splice-affecting, 93 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 160, Silent 93, Nonsense Mutation 13, Splice Site 4, Intron 3, Splice Region 1, 3'Flank 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1057519733, CM083720, COSV61068654; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 36/186 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- OTC | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); catalogued as rs72558417, CM1512785, CM950879, COSV50000745; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RELN | c.984G>A p.W328* | Nonsense Mutation (SNP) | VAF 34/146 reads (23%) | catalogued as rs1562961475, COSV58991405; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RPE65 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1553153243, COSV52014055; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SALL1 | c.3154C>T p.Q1052* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as rs1057518131, COSV51754818; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.1162C>T p.L388F | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs372031240, COSV66105956; called by muse, mutect2, varscan2
- AC011462.1 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs750739703, COSV54195851, COSV54196214; called by muse, mutect2, varscan2
- AC020907.6 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV59532938; called by muse, mutect2, varscan2
- ACTRT1 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64419054; called by muse, mutect2, varscan2
- ADAM7 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as COSV51535057; called by muse, mutect2, varscan2
- ADAMTS6 | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs770159566, COSV66857851; called by muse, mutect2, varscan2
- ADGRG6 | c.2760G>A p.W920* | Nonsense Mutation (SNP) | VAF 36/165 reads (22%) | catalogued as COSV51588296; called by muse, mutect2, varscan2
- ADGRV1 | c.11047G>A p.G3683R | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV67980709; called by muse, mutect2, varscan2
- ALKBH1 | c.855G>C p.L285F | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.344); catalogued as rs770497663, COSV53659103; called by muse, mutect2, varscan2
- ALX3 | c.821A>C p.Y274S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63928631; called by muse, mutect2
- ANKRD30A | c.898G>A p.E300K (on ENST00000611781; = p.E244K on NM_052997.2) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.931); catalogued as COSV64606483; called by muse, mutect2, varscan2
- APBA2 | c.859C>T p.L287F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.225); catalogued as COSV68794041; called by muse, mutect2, varscan2
- ARNTL | c.1027C>G p.R343G (on ENST00000403290 / NM_001297719.2; = p.R342G on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV62985705; called by muse, mutect2, varscan2
- ASB15 | c.1053G>C p.K351N | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs267601262, COSV51924555; called by muse, mutect2, varscan2
- ASTN1 | c.664G>T p.V222L | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.04); catalogued as COSV56064456, COSV56089433; called by muse, mutect2, varscan2
- ASXL3 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as COSV52460796; called by muse, mutect2, varscan2
- ASXL3 | c.4973G>A p.R1658K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV52460820; called by muse, mutect2, varscan2
- BMX | c.831G>A p.W277* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV59590616; called by muse, mutect2, varscan2
- BRDT | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1254168076, COSV62863559; called by muse, mutect2, varscan2
- BSND | c.157A>C p.M53L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV64870418; called by muse, mutect2, varscan2
- BTBD7 | c.2192G>A p.G731E | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58284305; called by muse, mutect2, varscan2
- BTBD7 | c.1559T>C p.V520A | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV58284312; called by muse, mutect2, varscan2
- C16orf46 | c.383G>A p.S128N | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV55150563; called by muse, mutect2, varscan2
- C2CD5 | c.2708C>T p.T903I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV61723624; called by muse, mutect2, varscan2
- CACNB4 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1374921337, COSV52390751, COSV52394751; called by muse, mutect2, varscan2
- CACNG5 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV50055021, COSV99400840; called by muse, mutect2, varscan2
- CCDC40 | c.2776T>C p.S926P | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV66473588; called by muse, mutect2, varscan2
- CCNT1 | c.1604T>C p.V535A | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs759891367, COSV56063530; called by muse, mutect2, varscan2
- CDKAL1 | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV51181031; called by muse, mutect2, varscan2
- CDON | c.3859A>G p.T1287A (on ENST00000392693 / NM_001243597.2; = p.T1264A on NM_016952.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.087); catalogued as COSV54996023; called by muse, mutect2, varscan2
- CEP135 | c.3307G>A p.E1103K | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57258744; called by muse, mutect2, varscan2
- CFAP65 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); catalogued as rs533998709, COSV55389706, COSV55391073; called by muse, mutect2, varscan2
- CHMP7 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.344); catalogued as COSV57532551; called by muse, mutect2, varscan2
- CLDN6 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as rs1309724762, COSV58509094; called by muse, mutect2, varscan2
- CLEC4M | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.759); catalogued as COSV50217116; called by muse, varscan2
- CNGA2 | c.1805G>A p.G602E | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61703708; called by muse, mutect2, varscan2
- CNNM4 | c.1276G>A p.D426N | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100998649, COSV65660409; called by muse, mutect2, varscan2
- CNTN5 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54291760; called by muse, mutect2, varscan2
- CNTNAP5 | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as COSV70478182; called by muse, mutect2, varscan2
- COL8A2 | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV57441078; called by muse, mutect2, varscan2
- CPA3 | c.256A>G p.K86E | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV56044238; called by muse, mutect2, varscan2
- CPAMD8 | c.4166G>A p.R1389Q (on ENST00000651564; = p.R1342Q on NM_015692.5) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs184781786, COSV71596032; called by muse, mutect2, varscan2
- CR1 | c.2292C>A p.D764E | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.971); catalogued as COSV65456794; called by mutect2, varscan2
- CRYGN | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.391); catalogued as rs946999048, COSV61563651; called by muse, mutect2, varscan2
- CSMD1 | c.7727G>A p.G2576E (on ENST00000520002; = p.G2575E on NM_033225.6) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.993); catalogued as COSV59296971, COSV59354655; called by muse, mutect2, varscan2
- CSMD2 | c.5297C>T p.A1766V | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs1353395396, COSV53890443; called by muse, mutect2, varscan2
- CYP2C19 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as rs866704734, COSV64907162; called by muse, mutect2, varscan2
- DAGLA | c.1213-1G>A p.X405_splice | Splice Site (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99944274, COSV99944564; called by muse, mutect2
- DAGLA | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99944565; called by muse, mutect2
- DISP3 | c.3319G>A p.G1107R | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1260662737, COSV53823063, COSV53825201; called by muse, mutect2, varscan2
- DNAH10 | c.12857G>A p.G4286E (on ENST00000409039; = p.G4225E on NM_207437.3) | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.612); catalogued as COSV99435730; called by muse, mutect2, varscan2
- DRD5 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58577181; called by muse, mutect2, varscan2
- DSC2 | c.2533G>A p.E845K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs1220943858, COSV51861499; called by muse, mutect2, varscan2
- DSCAML1 | c.3325G>A p.E1109K (on ENST00000321322; = p.E1049K on NM_020693.4) | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs201776853, COSV58385125; called by muse, mutect2, varscan2
- DSE | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs267600774, COSV59062498; called by muse, mutect2, varscan2
- DUSP22 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367730431; called by muse, mutect2, varscan2
- EPHA4 | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56028178, COSV56028802; called by muse, mutect2, varscan2
- FGF19 | c.581C>T p.T194I | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.146); catalogued as COSV53735998; called by muse, mutect2, varscan2
- FMN2 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777007362, COSV60422044; called by muse, mutect2, varscan2
- FRA10AC1 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63271222; called by muse, mutect2, varscan2
- GALNT17 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs778441180, COSV61152596; called by muse, mutect2, varscan2
- GALNT5 | c.1369A>T p.R457* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | catalogued as COSV52036489; called by muse, mutect2, varscan2
- GCOM1 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1449257847, COSV51088722; called by muse, mutect2, varscan2
- GFRAL | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.73); catalogued as COSV61229621; called by muse, mutect2, varscan2
- GRIN2B | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1249550681, COSV74205157; called by muse, mutect2, varscan2
- GRIP2 | c.2209G>A p.D737N (on ENST00000619221; = p.D640N on NM_001080423.4) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56120506; called by muse, mutect2, varscan2
- HNRNPA3 | c.203G>A p.R68K | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV66820711; called by muse, mutect2, varscan2
- HOXB1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 61/233 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776236487, COSV53316721, COSV53317945; called by muse, mutect2, varscan2
- IL4R | c.2272C>T p.P758S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.236); catalogued as COSV50139690; called by muse, mutect2, varscan2
- IRX1 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV57358499; called by muse, mutect2, varscan2
- JPH1 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs142292285, COSV60609580; called by muse, mutect2, varscan2
- KCNQ3 | c.740G>A p.W247* | Nonsense Mutation (SNP) | VAF 18/104 reads (17%) | catalogued as COSV66463751; called by muse, mutect2, varscan2
- KCTD3 | c.787G>T p.V263F | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99379534; called by muse, mutect2, varscan2
- KIAA1109 | c.2083C>T p.Q695* | Nonsense Mutation (SNP) | VAF 8/42 reads (19%) | catalogued as COSV52665749; called by muse, mutect2, varscan2
- KIF19 | c.231G>T p.Q77H | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63429062; called by muse, mutect2, varscan2
- KIF1B | c.4738G>A p.E1580K (on ENST00000377086 / NM_001365952.1; = p.E1534K on NM_015074.3) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV55805116; called by muse, mutect2, varscan2
- KYNU | c.582G>A p.E194= | Splice Region (SNP) | VAF 6/30 reads (20%) | catalogued as rs1463489882, COSV51580793; called by muse, mutect2, varscan2
- LEO1 | c.1916A>G p.K639R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV55175082; called by mutect2, varscan2
- LILRA1 | c.115A>C p.I39L | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as rs552034786, COSV52179254; called by muse, mutect2, varscan2
- LY9 | c.1343-1G>A p.X448_splice | Splice Site (SNP) | VAF 6/53 reads (11%) | catalogued as COSV54432362; called by muse, mutect2
- MAG | c.1522C>T p.R508* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as COSV62699509; called by muse, mutect2, varscan2
- MANSC1 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs1565792756, COSV67110741; called by muse, mutect2, varscan2
- MAP3K21 | c.1957G>A p.G653R | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.41); catalogued as COSV64041102; called by muse, mutect2, varscan2
- MARCO | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59052802; called by muse, mutect2, varscan2
- MDGA2 | c.1580G>A p.G527E (on ENST00000399232 / NM_001113498.2; = p.G229E on NM_182830.4) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV62082807; called by muse, mutect2, varscan2
- MICALL2 | c.1535C>T p.S512L | Missense Mutation (SNP) | VAF 64/236 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs543273285, COSV52514740; called by muse, mutect2, varscan2
- MMP26 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as rs371700941, COSV56171675; called by muse, mutect2, varscan2
- MORC1 | c.224-1G>A p.X75_splice | Splice Site (SNP) | VAF 16/69 reads (23%) | catalogued as COSV51716353; called by muse, mutect2, varscan2
- MRPL42 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as COSV62355664; called by muse, mutect2, varscan2
- MYCBPAP | c.1213G>A p.G405R | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60405968; called by muse, mutect2, varscan2
- MYH1 | c.4744G>A p.E1582K | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV56845217; called by muse, mutect2, varscan2
- MYH2 | c.2209C>T p.P737S | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV55432530; called by muse, mutect2, varscan2
- NADK | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); catalogued as rs201229178, COSV58270407; called by muse, mutect2, varscan2
- NCKAP1L | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 72/281 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.326); catalogued as rs958135628, COSV53204621; called by muse, mutect2, varscan2
- NFIX | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100666259, COSV62176190; called by muse, mutect2, varscan2
- NNT | c.2260A>C p.S754R | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV52923499; called by muse, mutect2, varscan2
- OGFOD3 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs767488958, COSV57339740; called by muse, mutect2, varscan2
- OR10A6 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs559631421, COSV59164725; called by muse, mutect2, varscan2
- OR2D2 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.059); catalogued as rs267603156, COSV55056623; called by muse, mutect2, varscan2
- OR4P4 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100111502, COSV58920801; called by muse, mutect2, varscan2
- OR52N1 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149811568, COSV57693416, COSV57693868; called by muse, mutect2, varscan2
- OR5P3 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.521); catalogued as rs868575374, COSV60428806, COSV60429207; called by muse, mutect2, varscan2
- OR6S1 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV57837731; called by muse, mutect2
- PAF1 | c.1405G>T p.E469* | Nonsense Mutation (SNP) | VAF 44/181 reads (24%) | catalogued as COSV55393017, COSV55395127; called by muse, mutect2, varscan2
- PAPPA | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV60279254; called by muse, mutect2, varscan2
- PAPPA | c.3391G>A p.D1131N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.515); catalogued as rs1306684113, COSV60278344; called by muse, mutect2, varscan2
- PAPPA2 | c.3623C>T p.S1208F | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.115); catalogued as rs267598192, COSV62792202; called by muse, mutect2, varscan2
- PCDH11Y | c.3575C>T p.P1192L | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.407); catalogued as rs768435179, COSV53077085; called by muse, mutect2, varscan2
- PCLO | c.14636C>T p.P4879L | Missense Mutation (SNP) | VAF 66/270 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61622876; called by muse, mutect2, varscan2
- PDE1C | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.614); catalogued as COSV100373567, COSV58506661; called by muse, mutect2, varscan2
- PDILT | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs373943417; called by muse, mutect2, varscan2
- PEG3 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs553693488, COSV55628621; called by muse, mutect2, varscan2
- PELP1 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as COSV52586565; called by muse, mutect2, varscan2
- PLCB4 | c.2365C>T p.L789F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs765407085, COSV53796401; called by muse, mutect2, varscan2
- POTEH | c.572G>A p.R191K | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.212); catalogued as COSV100625106, COSV100625145; called by muse, mutect2, varscan2
- PPFIA2 | c.2875C>T p.Q959* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV61024597; called by muse, mutect2, varscan2
- PRAMEF1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 65/304 reads (21%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.962); catalogued as COSV60007293; called by muse, mutect2, varscan2
- PRDM9 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.821); catalogued as COSV57003953, COSV57011326; called by muse, varscan2
- PRH2 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); catalogued as COSV101113330; called by muse, mutect2, varscan2
- PSG9 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 69/261 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs767140008, COSV52483990; called by muse, mutect2, varscan2
- PTPRF | c.1483G>A p.G495S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV63443643; called by muse, mutect2
- PTPRJ | c.2975G>A p.G992D | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1443048088, COSV69250544; called by muse, mutect2, varscan2
- RBL1 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.656); catalogued as COSV60328888; called by muse, mutect2, varscan2
- RINT1 | c.2074C>T p.L692F | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV57557793; called by muse, mutect2, varscan2
- RIPK1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52528466; called by muse, mutect2, varscan2
- ROS1 | c.3322C>T p.P1108S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV63851379; called by muse, mutect2, varscan2
- RYR2 | c.6292C>T p.L2098F | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV63671342; called by muse, mutect2, varscan2
- SART3 | c.2330C>T p.A777V (on ENST00000228284; = p.A759V on NM_014706.4) | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.82); PolyPhen benign (0.045); catalogued as rs1468313606, COSV57206132; called by muse, mutect2, varscan2
- SCN1A | c.3139G>A p.E1047K (on ENST00000303395 / NM_001202435.3; = p.E1036K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as rs776984527, CM113312, COSV57664062; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN9A | c.5578C>T p.R1860C (on ENST00000303354; = p.R1849C on NM_002977.3) | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs200494490, COSV57603782; called by muse, mutect2, varscan2
- SECISBP2L | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55933446; called by muse, mutect2, varscan2
- SELE | c.1735C>T p.R579W | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.34); catalogued as rs773892709, COSV60974465; called by muse, mutect2, varscan2
- SELP | c.1079T>G p.V360G | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV55249602; called by muse, mutect2, varscan2
- SH2D5 | c.803C>T p.P268L (on ENST00000444387 / NM_001103161.2; = p.P184L on NM_001103160.2) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.509); catalogued as COSV100903874; called by muse, mutect2
- SH3TC2 | c.3751G>A p.D1251N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV60461786; called by muse, mutect2, varscan2
- SHBG | c.781G>A p.G261S | Missense Mutation (SNP) | VAF 49/247 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52646377; called by muse, mutect2, varscan2
- SLC22A16 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1241288548, COSV57928215; called by muse, mutect2, varscan2
- SLC9C1 | c.2512G>A p.G838R | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV59886406; called by muse, mutect2, varscan2
- SLC9C2 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs866455639, COSV62944541; called by muse, mutect2, varscan2
- SLCO1A2 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56598935, COSV56605393; called by muse, mutect2, varscan2
- SMPD1 | c.805G>C p.A269P | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.21); catalogued as COSV54967025; called by muse, mutect2, varscan2
- SNAP91 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867775473, COSV52118182; called by muse, mutect2, varscan2
- SNCAIP | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs868339451, COSV54404791; called by muse, mutect2, varscan2
- SPATA31D1 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as rs372406686; called by muse, mutect2, varscan2
- SSTR1 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs1238965866, COSV57455322; called by muse, mutect2, varscan2
- ST3GAL1 | c.242C>T p.T81I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | PolyPhen benign (0.033); catalogued as rs199767300, COSV100172145, COSV60611175; called by muse, mutect2
- STEAP2 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55289685, COSV55290024; called by muse, mutect2, varscan2
- SUSD6 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61364853; called by muse, mutect2, varscan2
- SYNE1 | c.7651C>T p.P2551S (on ENST00000367255 / NM_182961.4; = p.P2558S on NM_033071.3) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV54932581; called by muse, mutect2, varscan2
- SYNJ2 | c.2293-1G>A p.X765_splice | Splice Site (SNP) | VAF 20/78 reads (26%) | catalogued as COSV62896068; called by muse, mutect2, varscan2
- TBX21 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 27/108 reads (25%) | catalogued as rs965811401, COSV51595325; called by muse, mutect2, varscan2
- TENM1 | c.557A>G p.N186S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.056); catalogued as COSV64427505; called by muse, mutect2, varscan2
- TEX47 | c.672G>A p.M224I | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.075); catalogued as rs1006291790, COSV51878335, COSV51878437; called by muse, mutect2, varscan2
- TGM4 | c.1480C>T p.L494F | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV56093192; called by muse, mutect2, varscan2
- TMEM102 | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.945); catalogued as COSV99548431, COSV99548432; called by muse, mutect2, varscan2
- TMTC2 | c.427G>T p.G143W | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1477099251, COSV58262649, COSV58264453; called by muse, mutect2, varscan2
- TRPC3 | c.1165G>A p.E389K (on ENST00000379645 / NM_001366479.2; = p.E316K on NM_003305.2) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV99313120; called by muse, mutect2, varscan2
- TTI1 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.061); catalogued as COSV65060914; called by muse, mutect2, varscan2
- TTN | c.31036G>A p.E10346K (on ENST00000591111; = p.E9419K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | PolyPhen benign (0.01); catalogued as COSV59941397; called by muse, mutect2, varscan2
- UGT2B15 | c.742T>C p.F248L | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57733477; called by muse, mutect2, varscan2
- VPS13B | c.7417C>T p.P2473S | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV62136417; called by muse, mutect2, varscan2
- VWA5A | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV63707395; called by muse, mutect2, varscan2
- VWA7 | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 97/341 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV65172749; called by muse, mutect2, varscan2
- WFDC8 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1568992836, COSV51488871; called by muse, mutect2, varscan2
- WFDC8 | c.104G>A p.W35* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV51488876; called by muse, mutect2, varscan2
- WFIKKN2 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60958189; called by muse, mutect2, varscan2
- ZFC3H1 | c.2465T>C p.V822A | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV66431071; called by muse, mutect2, varscan2
- ZNF200 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs763500352, COSV67723641; called by muse, mutect2, varscan2
- ZNF230 | c.1214C>T p.S405L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as COSV71273274; called by muse, mutect2, varscan2
- ZNF438 | c.987A>G p.I329M | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV59193143; called by muse, mutect2, varscan2
- ZSWIM8 | c.5114G>A p.G1705E (on ENST00000605216 / NM_001242487.2; = p.G1710E on NM_015037.3) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as COSV55213335; called by muse, mutect2, varscan2
- PLEKHA1 | c.76del p.L26Ffs*48 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.3235G>A p.E1079K (on ENST00000621492; = p.E1045K on NM_025248.3) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- ACTG2 | c.351G>A p.R117= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV61827831; called by muse, mutect2, varscan2
- ADAD1 | c.96G>A p.T32= | Silent (SNP) | VAF 34/62 reads (55%) | catalogued as rs755853675, COSV56641340; called by muse, mutect2, varscan2
- ADGRE1 | c.2400C>T p.A800= | Silent (SNP) | VAF 35/140 reads (25%) | catalogued as rs200479110, COSV51673220; called by muse, mutect2, varscan2
- AHNAK | c.9678C>T p.L3226= | Silent (SNP) | VAF 42/113 reads (37%) | catalogued as COSV57207200; called by muse, mutect2, varscan2
- ANKRD30A | c.3624C>T p.D1208= (on ENST00000611781; = p.D1152= on NM_052997.2) | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV64606490; called by muse, mutect2, varscan2
- APBA2 | c.858C>T p.L286= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV101382424; called by muse, mutect2, varscan2
- ARID5A | c.42G>A p.E14= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV62590846; called by muse, mutect2, varscan2
- ASXL3 | c.3660C>T p.T1220= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV52460807; called by muse, mutect2, varscan2
- BCL11B | c.2553G>A p.K851= (on ENST00000357195 / NM_001282237.2; = p.K780= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs1424138080, COSV61734492; called by muse, mutect2, varscan2
- BRINP3 | c.1167C>T p.I389= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs572813236, COSV66516971; called by muse, mutect2, varscan2
- BSN | c.6954C>T p.A2318= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV56514616; called by muse, mutect2, varscan2
- C6orf15 | c.417C>T p.S139= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs757073382, COSV52537533; called by muse, mutect2, varscan2
- CACNA1B | c.4416C>T p.P1472= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV53118140, COSV99497255; called by muse, mutect2, varscan2
- CACNA1H | c.4326C>T p.I1442= | Silent (SNP) | VAF 40/187 reads (21%) | catalogued as rs1171391522, COSV61986074; called by muse, mutect2, varscan2
- CAPN9 | c.162C>T p.S54= | Silent (SNP) | VAF 50/124 reads (40%) | catalogued as COSV55231640; called by muse, mutect2, varscan2
- CHD6 | c.7470C>T p.I2490= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as COSV64688989; called by muse, mutect2, varscan2
- CLCNKB | c.1764G>A p.Q588= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs765870330, COSV65152940; called by muse, mutect2, varscan2
- CMA1 | c.72G>A p.G24= | Silent (SNP) | VAF 31/137 reads (23%) | catalogued as COSV51625090; called by muse, mutect2, varscan2
- COL11A1 | c.3306G>A p.G1102= | Silent (SNP) | VAF 21/86 reads (24%) | catalogued as COSV62176145; called by muse, mutect2, varscan2
- COL6A3 | c.7893C>T p.T2631= | Silent (SNP) | VAF 46/169 reads (27%) | catalogued as COSV55083352; called by muse, mutect2, varscan2
- DLGAP2 | c.2466G>A p.R822= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV70096084; called by muse, mutect2, varscan2
- DNAH2 | c.9471C>T p.I3157= | Silent (SNP) | VAF 34/168 reads (20%) | catalogued as COSV66717655; called by muse, mutect2, varscan2
- DNAH2 | c.10086C>T p.T3362= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as COSV66717660; called by muse, mutect2, varscan2
- DUOX2 | c.1299C>T p.G433= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV66531171; called by muse, mutect2, varscan2
- E2F8 | c.2274C>T p.I758= | Silent (SNP) | VAF 33/128 reads (26%) | catalogued as COSV51462357; called by muse, mutect2, varscan2
- EFHD2 | c.429C>T p.D143= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as COSV65657914; called by muse, mutect2, varscan2
- EGLN3 | c.510G>A p.E170= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV51654220; called by muse, mutect2, varscan2
- FAM83H | c.2988C>T p.P996= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs1554621815, COSV62027675; called by muse, mutect2, varscan2
- FOXM1 | c.1296T>C p.P432= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV61205502; called by muse, mutect2, varscan2
- FREM1 | c.423G>A p.V141= | Silent (SNP) | VAF 46/136 reads (34%) | catalogued as COSV66519728; called by muse, mutect2, varscan2
- FUCA1 | c.816C>T p.H272= | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as COSV65698820; called by muse, mutect2, varscan2
- GNPAT | c.972C>T p.I324= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV64153139; called by muse, mutect2, varscan2
- GP2 | c.105C>T p.N35= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs1053484763, COSV56892562; called by muse, mutect2, varscan2
- GPR31 | c.342C>T p.L114= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV64761229; called by muse, mutect2, varscan2
- HECTD4 | c.8925G>A p.T2975= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs773329885, COSV101108084; called by muse, varscan2
- IFIT3 | c.732C>T p.L244= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV51078312; called by muse, mutect2, varscan2
- ITGA5 | c.1140C>T p.T380= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as COSV53216236; called by muse, mutect2, varscan2
- ITGA8 | c.687C>T p.I229= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV65226384; called by muse, mutect2, varscan2
- KCNAB1 | c.63G>A p.R21= | Silent (SNP) | VAF 45/168 reads (27%) | catalogued as COSV67484020; called by muse, mutect2, varscan2
- KIF21B | c.4176G>A p.V1392= (on ENST00000422435 / NM_001252100.2; = p.V1379= on NM_017596.4) | Silent (SNP) | VAF 23/134 reads (17%) | catalogued as COSV59754321; called by muse, mutect2, varscan2
- LAMB4 | c.3084C>T p.G1028= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs151001135; called by muse, mutect2, varscan2
- MC2R | c.633C>T p.P211= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as rs558388004, COSV59617409; called by muse, mutect2, varscan2
- MIEF2 | c.402C>T p.F134= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs544114638, COSV58943956; called by muse, mutect2, varscan2
- MST1R | c.2859C>T p.V953= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV56566111; called by muse, mutect2, varscan2
- MXRA5 | c.5037C>T p.S1679= | Silent (SNP) | VAF 73/142 reads (51%) | catalogued as COSV54228337; called by muse, mutect2, varscan2
- MYO3A | c.183G>A p.E61= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV56323550, COSV56325742; called by muse, mutect2, varscan2
- NAA25 | c.1267T>C p.L423= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV55702942; called by muse, mutect2, varscan2
- NDN | c.717C>T p.F239= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV59358887, COSV59359751; called by muse, mutect2, varscan2
- NLRP4 | c.1125C>T p.F375= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs373243158, COSV56710515; called by muse, mutect2, varscan2
- NOSIP | c.864G>A p.V288= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as rs528425276, COSV59198264; called by muse, mutect2, varscan2
- NPAP1 | c.1071C>T p.L357= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as COSV61505364; called by muse, mutect2, varscan2
- NPC1L1 | c.2124C>T p.S708= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV56923346; called by muse, mutect2, varscan2
- OR13H1 | c.414C>T p.G138= | Silent (SNP) | VAF 58/125 reads (46%) | catalogued as COSV58547201; called by muse, mutect2, varscan2
- OR2M3 | c.639C>T p.I213= | Silent (SNP) | VAF 111/328 reads (34%) | catalogued as COSV71758937; called by muse, mutect2, varscan2
- OR4K17 | c.666C>T p.L222= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as rs780616031, COSV59647539; called by muse, mutect2, varscan2
- OR4N5 | c.420C>T p.A140= | Silent (SNP) | VAF 41/229 reads (18%) | catalogued as COSV61320275; called by muse, mutect2, varscan2
- OR5D18 | c.906C>T p.V302= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100450790; called by muse, mutect2, varscan2
- OR5P2 | c.21G>A p.G7= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs1311409303, COSV61490117; called by muse, mutect2, varscan2
- OR5T3 | c.768C>T p.H256= | Silent (SNP) | VAF 26/141 reads (18%) | catalogued as rs939564903, COSV57379547, COSV57379819; called by muse, mutect2, varscan2
- OR6F1 | c.588G>A p.E196= | Silent (SNP) | VAF 71/155 reads (46%) | catalogued as rs1161460812, COSV57467198; called by muse, mutect2, varscan2
- PCDHGA3 | c.582G>A p.L194= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV53915591; called by muse, mutect2, varscan2
- PCDHGA5 | c.468C>T p.F156= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs1290164632, COSV53915605; called by muse, mutect2, varscan2
- PENK | c.405G>A p.R135= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as COSV100152511, COSV59240470; called by muse, mutect2, varscan2
- PRAMEF12 | c.444C>T p.I148= | Silent (SNP) | VAF 37/158 reads (23%) | catalogued as rs201538037; called by muse, mutect2, varscan2
- PRR14 | c.339T>C p.C113= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV54911076; called by muse, mutect2, varscan2
- PTPRT | c.1794C>T p.T598= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV61967881; called by muse, mutect2, varscan2
- RPTOR | c.2259G>A p.A753= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs774121223, COSV60805113; called by muse, mutect2, varscan2
- SCARF1 | c.60C>T p.S20= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs751484235, COSV99557164; called by mutect2, varscan2
- SCN10A | c.4272G>A p.Q1424= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs1370845738, COSV71860695; called by muse, mutect2, varscan2
- SCN4A | c.717C>T p.I239= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs568242866, COSV71126029; called by muse, mutect2, varscan2
- SEC61A1 | c.1155C>T p.S385= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs1392993107, COSV54576070; called by muse, mutect2, varscan2
- SIGLEC1 | c.1395C>T p.F465= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as COSV52459216; called by muse, mutect2, varscan2
- SIGLEC8 | c.648G>A p.Q216= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV58472758; called by muse, mutect2, varscan2
- SLC26A3 | c.567C>T p.I189= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV60639285; called by muse, mutect2
- SLC44A5 | c.528A>G p.K176= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV63760042; called by muse, mutect2
- SLC8B1 | c.1188C>T p.I396= | Silent (SNP) | VAF 26/89 reads (29%) | catalogued as rs138371135, COSV52526232; called by muse, mutect2, varscan2
- SPTB | c.5481C>T p.D1827= | Silent (SNP) | VAF 29/113 reads (26%) | catalogued as rs752281367, COSV67630470; called by muse, mutect2, varscan2
- SPTBN5 | c.3162C>T p.F1054= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV58018109; called by muse, mutect2, varscan2
- SUGP2 | c.2913C>A p.L971= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV58256403; called by muse, varscan2
- TC2N | c.1170C>T p.F390= | Silent (SNP) | VAF 43/167 reads (26%) | catalogued as rs776984565, COSV61746360, COSV61747345; called by muse, mutect2, varscan2
- TFPI | c.126G>A p.T42= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs761938631, COSV51899467; called by muse, mutect2, varscan2
- THRSP | c.408G>A p.R136= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV55246064; called by muse, mutect2, varscan2
- TMEM102 | c.306G>A p.G102= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV99548433; called by muse, mutect2, varscan2
- TMEM125 | c.612T>C p.S204= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV71326911; called by muse, mutect2, varscan2
- TNFRSF10A | c.1035G>A p.G345= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as rs763343735, COSV55325094; called by muse, mutect2, varscan2
- TNNT3 | c.435G>A p.K145= (on ENST00000397301 / NM_001367846.1; = p.K134= on NM_006757.4) | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV53485363; called by muse, mutect2, varscan2
- VPS13D | c.2733T>G p.T911= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV50626913; called by muse, mutect2, varscan2
- WDR62 | c.1671G>A p.R557= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99543968; called by muse, mutect2
- WEE2 | c.522G>A p.R174= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs764316650, COSV66878473; called by muse, mutect2, varscan2
- ZBTB46 | c.1335C>T p.P445= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs994486759, COSV55507801; called by muse, mutect2, varscan2
- ZNF226 | c.978G>A p.Q326= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs267605534, COSV56196214; called by muse, mutect2, varscan2
- ZNF229 | c.1632C>T p.P544= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as COSV52160572; called by muse, mutect2, varscan2
- ZPLD1 | c.1168C>T p.L390= (on ENST00000466937 / NM_001329788.1; = p.L406= on NM_175056.2) | Silent (SNP) | VAF 61/217 reads (28%) | catalogued as rs1429650829, COSV60352448; called by muse, mutect2, varscan2
- DCAF13 | chr8:103415328 C>T | 5'Flank (SNP) | VAF 23/101 reads (23%) | catalogued as COSV52567086; called by muse, mutect2, varscan2
- EEF1D | c.-7-2321C>T | Intron (SNP) | VAF 12/50 reads (24%) | catalogued as rs540105277, COSV57818144; called by muse, mutect2, varscan2
- GRM7 | c.2698+6080G>A | Intron (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100737537; called by muse, mutect2, varscan2
- JAKMIP1 | chr4:6049827 C>T | 3'Flank (SNP) | VAF 12/45 reads (27%) | catalogued as rs1274174883, COSV51524978; called by muse, mutect2, varscan2
- ZNF174 | c.625+309C>T | Intron (SNP) | VAF 10/56 reads (18%) | catalogued as rs1439925569, COSV99237609; called by muse, mutect2, varscan2
